Somatic mutation profile of tumor specimen TCGA-A2-A04Y-01A (aliquot TCGA-A2-A04Y-01A-21W-A050-09) from TCGA case TCGA-A2-A04Y, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 53.5 years (19,533 days).
Specimen TCGA-A2-A04Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2ab022b-086e-491a-b9ff-d4b0a696a5da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A04Y-10A (Blood Derived Normal), aliquot TCGA-A2-A04Y-10A-01W-A055-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6a206bd-ca60-47a5-8338-acace9d4bc55

The open-access MAF lists 40 somatic variants for this specimen: 36 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 30, Silent 4, Frame Shift Del 2, Frame Shift Ins 1, In Frame Del 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1G2 | c.361G>A p.G121S | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.889); catalogued as COSV58114522; called by muse, mutect2, varscan2
- BDKRB2 | c.1133G>T p.R378L | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.071); catalogued as rs778370159, COSV60016044, COSV60016228; called by muse, mutect2, varscan2
- C1orf50 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV52536039; called by mutect2, varscan2
- CALCRL | c.1220G>C p.G407A | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as COSV101131056, COSV66476376; called by muse, mutect2, varscan2
- CALU | c.71A>G p.K24R | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV50822691; called by muse, mutect2, varscan2
- CAMSAP1 | c.3921G>T p.Q1307H | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56725986; called by muse, mutect2, varscan2
- CPXCR1 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1477949802, COSV52163884; called by muse, mutect2, varscan2
- DYNC1LI2 | c.851A>G p.Y284C | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV50755670; called by muse, mutect2, varscan2
- ENPP2 | c.1598A>G p.H533R (on ENST00000075322 / NM_001040092.3; = p.H585R on NM_006209.5) | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as rs1352519988, COSV50027251; called by muse, mutect2, varscan2
- FAM200A | c.655G>A p.G219R | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs901506959, COSV68808519; called by muse, mutect2
- GRK3 | c.292G>C p.E98Q | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as COSV100151042; called by muse, mutect2
- HRH1 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.931); catalogued as rs773371879, COSV67955157; called by muse, mutect2, varscan2
- ICE2 | c.1805G>T p.R602I | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99831263; called by muse, mutect2
- IPO8 | c.1123G>C p.E375Q | Missense Mutation (SNP) | VAF 106/227 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56244259; called by muse, mutect2, varscan2
- ITGB1BP2 | c.796G>T p.A266S | Missense Mutation (SNP) | VAF 22/410 reads (5%) | SIFT tolerated (0.61); PolyPhen benign (0.285); catalogued as COSV99338547; called by muse, mutect2
- KIF5B | c.1720G>T p.V574L | Missense Mutation (SNP) | VAF 8/175 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100191352; called by muse, mutect2
- LDB2 | c.363C>A p.D121E | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.791); catalogued as COSV58776843, COSV99072867; called by muse, mutect2, varscan2
- LRP12 | c.320G>A p.W107* | Nonsense Mutation (SNP) | VAF 10/133 reads (8%) | catalogued as COSV99407103; called by muse, mutect2
- MANBA | c.1522C>A p.L508M (on ENST00000642252; = p.L462M on NM_005908.4) | Missense Mutation (SNP) | VAF 17/274 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99898272; called by muse, mutect2
- NDST1 | c.2011G>A p.D671N | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.978); catalogued as rs1011218498, COSV55786014, COSV99938614; called by muse, mutect2
- NR1H4 | c.691G>C p.D231H (on ENST00000551379 / NM_001206993.2; = p.D217H on NM_005123.4) | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs746732391, COSV51855071; called by muse, mutect2, varscan2
- OMA1 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV100677907; called by muse, mutect2
- P2RX5 | c.709G>A p.V237M | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.393); catalogued as rs1050281, COSV56593229; called by muse, mutect2, varscan2
- PIP4K2A | c.362C>A p.P121H | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV60541955; called by muse, mutect2, varscan2
- PLXNB1 | c.6394G>T p.V2132F | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99602197; called by muse, mutect2, varscan2
- SOX6 | c.1967G>A p.G656E (on ENST00000528429 / NM_001145819.2; = p.G629E on NM_017508.3) | Missense Mutation (SNP) | VAF 45/200 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57053405; called by muse, mutect2, varscan2
- ST8SIA4 | c.469G>C p.G157R | Missense Mutation (SNP) | VAF 13/45 reads (29%) | PolyPhen probably damaging (1); catalogued as COSV51514943, COSV99185094; called by muse, mutect2
- TIAM2 | c.3884_3886del p.K1295del | In Frame Del (DEL) | VAF 21/103 reads (20%) | catalogued as rs779923938; called by pindel, varscan2
- TNC | c.2848A>G p.T950A | Missense Mutation (SNP) | VAF 71/304 reads (23%) | SIFT tolerated (0.95); PolyPhen benign (0.009); catalogued as COSV60788377; called by muse, mutect2, varscan2
- TP53BP2 | c.2138C>A p.S713Y (on ENST00000343537 / NM_001031685.3; = p.S584Y on NM_005426.2) | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as rs189590424, COSV100636497, COSV59066985; called by muse, mutect2, varscan2
- ARNTL | c.139_140+3del p.X47_splice | Splice Site (DEL) | VAF 14/68 reads (21%) | called by mutect2, pindel, varscan2
- EGR3 | c.285del p.N96Tfs*11 | Frame Shift Del (DEL) | VAF 11/19 reads (58%) | called by mutect2, pindel, varscan2
- FHDC1 | c.2174C>A p.T725K | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.038); called by muse, mutect2
- KIAA0232 | c.905del p.N302Ifs*5 | Frame Shift Del (DEL) | VAF 6/51 reads (12%) | called by mutect2, pindel, varscan2
- NBPF26 | c.2500C>T p.P834S (on ENST00000620612; = p.P572S on NM_001351372.1) | Missense Mutation (SNP) | VAF 83/183 reads (45%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- PXDN | c.671_672dup p.P225Ifs*18 | Frame Shift Ins (INS) | VAF 29/128 reads (23%) | called by mutect2, pindel, varscan2
- GIGYF1 | c.150C>T p.Y50= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as rs375425147; called by muse, mutect2, varscan2
- MMP16 | c.75C>T p.T25= | Silent (SNP) | VAF 56/817 reads (7%) | catalogued as COSV99685850; called by muse, mutect2
- NOL8 | c.1353T>G p.S451= | Silent (SNP) | VAF 35/97 reads (36%) | catalogued as COSV62636705; called by muse, mutect2, varscan2
- PCDH19 | c.1656C>T p.I552= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs779051005, COSV99718953; called by muse, varscan2
